Somatic mutation profile of tumor specimen 9efd41a5-3db1-445b-accb-040c2b (aliquot 9efd41a5-3db1-445b-accb-040c2b_D6_1) from CPTAC case 11BR024, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.7 years (29,473 days).
Specimen 9efd41a5-3db1-445b-accb-040c2b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c37a8a7d-44e8-4fd6-9937-f70cad94dff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen e2366c0d-43f0-4761-9b7b-7a94ac (Blood Derived Normal), aliquot e2366c0d-43f0-4761-9b7b-7a94ac_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bf21947-c31d-41d0-942a-c76a3e8aa062

The open-access MAF lists 75 somatic variants for this specimen: 48 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 18, Intron 4, Frame Shift Del 2, Nonsense Mutation 2, 3'UTR 2, 5'UTR 1, Splice Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 140/414 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.1120A>C p.K374Q | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV52207517; called by muse, mutect2
- ANKRD18B | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs932101283; called by muse, mutect2, varscan2
- COPB1 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100000009; called by muse, mutect2
- EHBP1L1 | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 32/255 reads (13%) | catalogued as COSV58571493; called by mutect2, pindel, varscan2
- EHF | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57667858; called by muse, mutect2, varscan2
- FOLR3 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs371010355; called by muse, mutect2
- GFUS | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770039732; called by muse, mutect2, varscan2
- HOOK3 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV56881311; called by muse, mutect2, varscan2
- ITFG2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755055441; called by muse, mutect2, varscan2
- LZTR1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769001939, COSV53145056; called by muse, varscan2
- NRIP1 | c.1821C>A p.D607E | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59659534; called by muse, mutect2
- NRXN1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 49/435 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV68035502; called by muse, mutect2, varscan2
- NUDT19 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs766150799; called by muse, mutect2, varscan2
- OR2T34 | c.588C>G p.D196E | Missense Mutation (SNP) | VAF 66/904 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV60900244; called by muse, mutect2
- PIK3C2B | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs867787593; called by muse, mutect2
- PLXNB1 | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140699424; called by muse, mutect2, varscan2
- PRDM13 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs747843877, COSV65029167; called by muse, mutect2, varscan2
- RRN3 | c.299T>C p.M100T | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779705782; called by muse, mutect2, varscan2
- SYTL2 | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 60/665 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV60362669; called by muse, mutect2
- ZNF628 | c.2555C>T p.T852I | Missense Mutation (SNP) | VAF 55/482 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs762448718; called by muse, mutect2, varscan2
- ARHGAP35 | c.2866A>G p.N956D | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C14orf93 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CALD1 | c.1068G>T p.R356S | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRLF3 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD1 | c.4690G>A p.A1564T (on ENST00000520002; = p.A1563T on NM_033225.6) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CUL5 | c.2142A>T p.R714S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DAB1 | c.1293G>C p.R431S (on ENST00000371231; = p.R398S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FOXO3 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 94/1031 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2
- GRIA4 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- KMT2A | c.8278G>T p.D2760Y | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- LILRA1 | c.530G>A p.W177* | Nonsense Mutation (SNP) | VAF 52/430 reads (12%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAML3 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYO9B | c.5170G>C p.E1724Q | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEK1 | c.1080+1G>A p.X360_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- NFE2L3 | c.928A>C p.S310R | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- NRXN3 | c.28T>C p.F10L | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- NUBP2 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PAPPA2 | c.4868_4871del p.N1623Rfs*37 | Frame Shift Del (DEL) | VAF 34/133 reads (26%) | called by mutect2, varscan2
- PIP4P2 | c.487T>A p.W163R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RNF220 | c.1661C>G p.T554R | Missense Mutation (SNP) | VAF 65/367 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SAFB | c.2453G>A p.R818K | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2
- SOX1 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 58/550 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, varscan2
- SREBF2 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- VDAC1 | c.345G>C p.K115N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- WNT2 | c.434C>G p.A145G | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF224 | c.1454A>G p.Q485R | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.102); called by muse, mutect2
- CACNA1E | c.3843C>T p.C1281= | Silent (SNP) | VAF 24/272 reads (9%) | catalogued as rs373094161; called by muse, mutect2
- CSPG4 | c.4524T>C p.D1508= | Silent (SNP) | VAF 42/604 reads (7%) | called by muse, mutect2
- DDC | c.1413G>A p.A471= | Silent (SNP) | VAF 134/442 reads (30%) | catalogued as rs528137159, COSV63567360; called by muse, mutect2, varscan2
- DNAH7 | c.11967C>T p.T3989= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs762361155; called by muse, mutect2
- KCNH2 | c.1149C>T p.D383= | Silent (SNP) | VAF 31/217 reads (14%) | catalogued as rs201995634, COSV100059468; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- KNTC1 | c.6450G>A p.L2150= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- MDC1 | c.6183G>T p.S2061= | Silent (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- MYORG | c.672C>T p.I224= | Silent (SNP) | VAF 42/696 reads (6%) | called by muse, mutect2
- NDUFAB1 | c.207C>T p.S69= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs764029297; called by mutect2, varscan2
- NLRP3 | c.1923G>A p.V641= | Silent (SNP) | VAF 28/498 reads (6%) | called by muse, mutect2
- POM121L2 | c.627G>A p.V209= | Silent (SNP) | VAF 38/394 reads (10%) | called by muse, mutect2
- PPP3R2 | c.387C>T p.L129= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as COSV100701525; called by muse, mutect2, varscan2
- PRR35 | c.663C>T p.S221= | Silent (SNP) | VAF 50/246 reads (20%) | called by muse, mutect2, varscan2
- PSME1 | c.108G>A p.K36= | Silent (SNP) | VAF 38/296 reads (13%) | called by muse, mutect2, varscan2
- PSME1 | c.477G>C p.L159= | Silent (SNP) | VAF 50/319 reads (16%) | called by mutect2, varscan2
- SWSAP1 | c.429C>G p.T143= (on ENST00000312423; = p.T164= on NM_175871.4) | Silent (SNP) | VAF 90/330 reads (27%) | called by muse, mutect2, varscan2
- TMEM87A | c.1215C>T p.T405= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- ULK4 | c.879C>T p.V293= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs370248293; called by muse, mutect2, varscan2
- CERS2 | c.-41-2735C>T | Intron (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- DDX47 | c.1035+12T>G | Intron (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- DNMT1 | c.3901-30G>A | Intron (SNP) | VAF 85/237 reads (36%) | catalogued as rs368933609; called by muse, mutect2, varscan2
- GPATCH8 | c.*486G>A | 3'UTR (SNP) | VAF 118/326 reads (36%) | called by muse, mutect2, varscan2
- GRHL1 | c.-3G>A | 5'UTR (SNP) | VAF 5/41 reads (12%) | catalogued as rs770035226; called by mutect2, varscan2
- HCAR2 | c.*50G>T | 3'UTR (SNP) | VAF 6/115 reads (5%) | called by muse, mutect2
- HS1BP3 | c.406+56C>T | Intron (SNP) | VAF 19/87 reads (22%) | catalogued as rs775171428; called by muse, mutect2, varscan2
- MIR548A2 | n.66C>T | RNA (SNP) | VAF 47/220 reads (21%) | called by muse, mutect2, varscan2
- PRDM10 | chr11:130003321 C>A | 5'Flank (SNP) | VAF 3/38 reads (8%) | catalogued as rs1023173144; called by muse, mutect2
